Surgical pathology report (de-identified scan), TCGA case TCGA-QA-A7B7, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Emory University, specimen TCGA-QA-A7B7-01A (Primary Tumor).

[page 1 of 3]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status: Auth (Verified)
Document Title: Histology
Performed By:
Verified By:
Encounter info:

* Final Report *

(Verified)

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver (22.0)
QJ 8/21/13

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

Copy To Phys:

DOB:

Gender:

M

(Age:

Acc #:

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. LIVER AND DIAPHRAGM, RIGHT LOBE, PARTIAL HEPATECTOMY:

- HEPATOCELLULAR CARCINOMA, MODERATE TO POORLY DIFFERENTIATED (6.8 X 5.0 CM).
- CARCINOMA INVADERS INTO THE PERIDIAPHRAGMATIC SOFT TISSUE AND IS 2 MILLIMETERS AWAY FROM THE DIAPHRAGMATIC MARGIN. CARCINOMA IS 8 MILLIMETERS FROM PARENCHYMAL RESECTION MARGIN.

- VASCULAR INVASION IS PRESENT.

- UNINVOLVED LIVER SHOWS FOCAL MINIMAL PORTAL INFLAMMATION BUT NO OTHER SPECIFIC PATTERNS

OF INJURY. NO EVIDENCE OF CIRROSIS.

- GALLBLADDER WITH CHOLESTROLOSIS.

Electronically Signed by

Printed by:

Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Synoptic Worksheet

A. Right liver lobe with diaphragm:

Clinical History:	Hepatitis B infection
Specimen:	Liver Gallbladder
Procedure:	Partial hepatectomy
Tumor Size:	Greatest dimension: 6.8 cm Additional dimension: 5.0 cm
Tumor Focality:	Solitary, location: segment 7
Histologic Type:	Hepatocellular carcinoma
Histologic Grade:	Other: Moderate to poorly differentiated
Tumor Extension:	Tumor directly invades other adjacent organs: Diaphragm
Margins:	Parenchymal margin uninvolved by invasive carcinoma Distance of invasive carcinoma from closest margin: 2 mm Margin: Diaphragmatic margin Other margin: Parenchymal margin (8 mm), uninvolved by invasive carcinoma
Lymph-Vascular Invasion:	Macroscopic Venous (Large Vessel) Invasion (V) not identified Microscopic (Small Vessel) Invasion (L) present
Perineural Invasion:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assessed Number of nodes examined: 0 Number of nodes involved: 0
Distant Metastasis (pM):	Distant Metastasis (pM), not applicable
Additional Pathologic Findings:	Chronic hepatitis, etiology: Focal mild non-specific chronic portal inflammation

Clinical History

Right hepatectomy.

Specimen(s) Received

A: Right liver lobe with diaphragm

Gross Description

The specimen is received fresh, labeled with the patient's name, medical record number and designated "right liver lobe with diaphragm." It consists of a partial hepatectomy with attached gallbladder and a loosely attached fragment of diaphragm. The specimen weighs 362.0 grams and measures as follows: liver 19.0 x 10.0 x 3.5 cm, gallbladder 8.5 x 4.7 x 1.8 cm and diaphragm

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

8.0 x 3.0 x 0.3 cm. There is a 6.8 x 5.0 x 4.5 cm well circumscribed yellow mass identified 0.7 cm from the closest resection margin and 4.9 cm from the gallbladder. The mass grossly invades the liver capsule and possibly so involvement of the diaphragm. The liver mass beneath the diaphragm is fragmented and disrupted. No other lesions are identified. The gallbladder is remarkable for cholesterosis but is otherwise unremarkable. The gallbladder wall measures up to 0.4 cm in thickness. The specimen is inked as follows: cauterized resection margin black, diaphragm blue. A representative section of the mass as well with uninvolved liver is submitted to Tissue Procurement Services. Representative sections are submitted as stated below. (Dictated by

CASSETTE SUMMARY:

A1: Mass closest to resection margin
A2: Mass in relationship to capsule
A3: Mass in relationship to normal liver
A4,5: Mass in relationship to diaphragm
A6: Additional representative diaphragm
A7: Uninvolved liver
A8: Representative gallbladder

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Criteria	W 5/18/13	Yes	No

Source: NCI Genomic Data Commons file 16e5fd02-0132-4112-851b-450be8089b8b (TCGA-QA-A7B7.20257CE0-FCFF-41B4-B9A3-47397B147ED8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).